Surgical pathology report (de-identified scan), TCGA case TCGA-06-0649, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-0649-01B (Primary Tumor).

[page 1 of 3]
Surgical Pathology Report
*** AMENDED ***

TCGA-06-0649

CLINICAL HISTORY

[REDACTED] with possible stroke and seizures, has heterogenously enhancing left temporal tumor with edema and mass effect.

OPERATIVE DIAGNOSES

Not Given

Operation/Specimen: A: Brain, Left temporal, biopsy
B: Brain, left temporal tumor, biopsy

PATHOLOGICAL DIAGNOSIS:

A and B. Brain, left temporal, excisional biopsies: Glioblastoma.
See Comment.

COMMENT

The specimens are fragments of an astrocytic neoplastic proliferation that focally infiltrates and extensively effaces the brain tissue. The neoplasm has nuclear anaplasia, mitotic figures, microvascular cellular proliferation with necrosis and thrombosis, and zones of tumor necrosis, i.e. a glioblastoma.

Special stains to better characterize the neoplasm have been requested and results will be reported as an addendum.

AMENDMENTS

Amended: [REDACTED]

Reason: Report, Dictation, Typographical Error

The case was signed out before the gross was transcribed.

Previous Signout Date: [REDACTED]

PROCEDURES/ADDENDA

Immunohistology

Date Ordered: [REDACTED] Date Reported: [REDACTED]

Interpretation

[page 2 of 3]
Brain, Immunohistochemistry: MIB-1 proliferation index .
See Results and Comment (below).

Results-Comments

IMMUNOHISTOCHEMISTRY: The GFAP depicts gliofibrillogenesis by the neoplastic cells. The tumor cells do not over express the p53 protein. With the MIB-1 there is a proliferation index of about 23% in the more active areas.

Comment: The results are those of a glioblastoma.

INTRA-OPERATIVE CONSULTATION

A.

Brain, touch prep and smears: High histological grade glioma (glioblastoma).

GROSS DESCRIPTION

A.

"Brain, Left temporal, biopsy," received fresh, four fragments, 0.6 cm. across in aggregate. Semi firm, glistening, tannish-grey. In total, A1.

B.

SPECIMEN: Left temporal tumor.

FIXATIVE: None.

GENERAL: Several fragments of tan rubbery brain parenchyma with red clotted blood, 3 cm in loose aggregate.

SECTIONS: B1-B3 all submitted.

ICD-9(s):
225.0 225.0

Histo Data

Part A: Brain, Left temporal, biopsy

Taken:	Received:	Block	Ordered	Comment
Stain/cnt				
FS H/E x 1		1		
mGFAP-DA x 1		1		
H/E x 1		1		
MIB1-DA x 1		1		
P53DO7 x 1		1		
H/E x 1		2		

Part B: Brain, left temporal tumor, biopsy

Taken:	Received:	Block	Ordered	Comment
Stain/cnt				
H/E x 1		1		

[page 3 of 3]
H/E x 1 2
H/E x 1 3

*** End of Report ***

Source: NCI Genomic Data Commons file 45e79aa7-c02d-45c5-a332-b4616ad930d8 (TCGA-06-0649.81BA5108-B92B-4D5C-AB65-134AFC0D3173.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).